Somatic mutation profile of tumor specimen MP2PRT-PATJLH-TMP1-B (aliquot MP2PRT-PATJLH-TMP1-B-1-0-D-A817-36) from MP2PRT case MP2PRT-PATJLH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (962 days).
Specimen MP2PRT-PATJLH-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72e0a0d8-56b1-495c-b7c7-6f15ee3c0657.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJLH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJLH-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d10bf0d3-8512-4291-b5cc-613885ca6fc4

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 80/214 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AATK | c.1055G>A p.R352Q (on ENST00000326724 / NM_001080395.3; = p.R249Q on NM_004920.2) | Missense Mutation (SNP) | VAF 107/360 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs940674878, COSV58688335; called by muse, mutect2, varscan2
- HMGXB4 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as rs528331783; called by muse, mutect2, varscan2
- KLHDC7A | c.2158G>A p.V720M | Missense Mutation (SNP) | VAF 137/340 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs774526487, COSV68769965; called by muse, mutect2, varscan2
- LAMA3 | c.3437C>T p.S1146L | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs766421324, COSV58073782; called by muse, varscan2
- NEURL3 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 24/537 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as rs1197583768; called by muse, mutect2
- PLXNC1 | c.2408C>T p.A803V | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.137); catalogued as rs749923591, COSV99313959; called by muse, mutect2, varscan2
- MDFIC | c.628del p.D210Mfs*67 | Frame Shift Del (DEL) | VAF 93/281 reads (33%) | called by mutect2, pindel, varscan2
- OTX2 | c.768C>G p.C256W (on ENST00000408990 / NM_172337.3; = p.C264W on NM_021728.4) | Missense Mutation (SNP) | VAF 90/365 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SYK | c.1160A>G p.K387R | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2
- TENM2 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2
- ZNF728 | c.1795A>G p.K599E | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2
- CCDC149 | c.1101C>T p.S367= (on ENST00000635206 / NM_001330643.2; = p.S356= on NM_173463.5) | Silent (SNP) | VAF 73/340 reads (21%) | catalogued as rs767170047; called by muse, mutect2, varscan2
- CPZ | c.1239G>T p.L413= (on ENST00000360986 / NM_001014447.3; = p.L402= on NM_003652.3) | Silent (SNP) | VAF 66/242 reads (27%) | called by muse, mutect2, varscan2
